Gene-level copy-number profile of tumor specimen TCGA-18-3416-01A from TCGA case TCGA-18-3416, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 83.3 years (30,435 days).
Specimen TCGA-18-3416-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.d72837b0-85f7-4263-a3b6-03ee64abee5b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-18-3416-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/231de1f1-8d36-4ed8-8fa6-5aee199c8a49

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 1,229; copy number 2: 24,123; copy number 3: 17,448; copy number 4: 13,711; copy number 5: 1,410; copy number 6: 513; copy number 7: 452; copy number 8: 125; copy number 9: 94; copy number 10: 219; copy number 11: 13; copy number 12: 78; copy number 13: 246; copy number 14: 25; copy number 15: 15; copy number 18: 44; copy number 20: 36; copy number 22: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-18-3416-01A-01D-0978-01): tumor purity 0.51, ploidy 2.99, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,745–409,417, 7 genes (within-gene range 0–2): LINC01986, AC066595.1, CHL1-AS2, AC066595.2, CHL1, RNU6-1194P, RPS8P6.
- chr5:50,396,192–51,167,647, 14 genes: EMB, AC112187.2, AC112187.1, AC112187.3, PARP8, AC022441.1, AC022441.3, AC022441.2, AC008808.2, LINC02106, AC008808.1, RNU6-480P, AC091834.1, RNU6-1296P.
- chr10:36,626,015–36,626,138, 1 gene: Y_RNA.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,274 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–2,817,767, 173 genes, copy number 6 (broad region; genes not listed).
- chr1:232,160,091–233,672,514, 21 genes, copy number 5: AL353052.1, AL353052.2, BX323014.1, RN7SL299P, SIPA1L2, RNU6-1211P, LINC01745, LINC01744, MAP10, RNU1-74P, AL122003.2, AL122003.1, NTPCR, PCNX2, RPS7P3, AL133380.1, MAP3K21, RNU4-77P, AL360006.1, KCNK1, MIR4427.
- chr2:38,814–950,274, 27 genes, copy number 5–6: FAM110C, AC079779.1, SH3YL1, ACP1, ALKAL2, AC079779.2, AC079779.3, AC079779.4, LINC01865, AC105393.2, AC105393.1, LINC01874, AC093326.2, LINC01875, AC093326.1, TMEM18, TMEM18-DT, AC092159.3, AC092159.2, AC092159.1, AC116609.3, AC116609.2, AC116609.1, LINC01115, LINC01939, AC113607.1, SNTG2-AS1.
- chr2:1,059,133–1,068,341, 1 gene, copy number 6: AC114808.1.
- chr2:46,490,750–61,605,722, 210 genes, copy number 6–8 (within-gene range 3–8) (broad region; genes not listed).
- chr2:176,077,472–176,119,937, 5 genes, copy number 7: EVX2, HOXD13, HOXD12, HOXD11, HOXD10.
- chr2:176,495,255–179,861,612, 72 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).
- chr2:209,145,241–211,105,732, 22 genes, copy number 7–22 (within-gene range 5–22): CRYGFP, MEAF6P1, PKP4P1, AC016743.1, MAP2, RNA5SP118, UNC80, SNAI1P1, RPE, KANSL1L, AC007038.1, KANSL1L-AS1, RPL6P6, AC006994.1, ACADL, Y_RNA, MYL1, LANCL1-AS1, LANCL1, CPS1, CPS1-IT1, AC012491.1.
- chr3:109,409,990–109,723,273, 1 gene, copy number 5 (within-gene range 3–5): LINC01205.
- chr3:109,602,828–111,071,553, 10 genes, copy number 5: MIR4445, AC078980.1, DIMT1P1, NFYBP1, AC078918.1, AC117430.1, RNU6ATAC15P, RPSAP29, Y_RNA, NECTIN3-AS1.
- chr3:141,324,213–188,154,057, 771 genes, copy number 6–20 (within-gene range 2–20) (broad region; genes not listed).
- chr3:188,178,543–188,180,812, 1 gene, copy number 7: FLJ42393.
- chr3:188,941,715–198,222,513, 217 genes, copy number 7 (broad region; genes not listed).
- chr4:168,356,735–169,270,956, 16 genes, copy number 6 (within-gene range 4–6): DDX60L, AC079926.1, PALLD, BTF3L4P4, PALLD-AS1, RNU6-1336P, RPL9P16, AC080188.1, AC080188.2, CBR4, RNU6-853P, RNY4P17, AC021151.1, SH3RF1, RPL6P12, AC096741.1.
- chr7:70,972–727,650, 21 genes, copy number 8 (within-gene range 4–8): AC093627.1, AC093627.6, AC093627.22, AC093627.5, AC093627.4, AC093627.7, AC093627.2, AC093627.3, FAM20C, AC145676.1, FOXL3, AC188616.1, AC226118.1, AC188617.1, AC188617.2, AC147651.1, PDGFA, HRAT92, PRKAR1B, PRKAR1B-AS2, PRKAR1B-AS1.
- chr7:18,807,993–24,981,634, 96 genes, copy number 6–20 (broad region; genes not listed).
- chr8:37,843,268–40,402,010, 69 genes, copy number 6 (broad region; genes not listed).
- chr8:67,732,587–69,104,242, 13 genes, copy number 5 (within-gene range 4–5): AC022874.1, NDUFS5P6, PREX2, AC011853.2, AC011853.1, Y_RNA, RPL31P40, C8orf34-AS1, C8orf34, RPS15AP25, RNA5SP269, AC083967.1, LINC01592.
- chr10:44,712–17,716,824, 308 genes, copy number 5 (broad region; genes not listed).
- chr10:36,940,109–42,638,570, 68 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr10:59,551,404–61,026,420, 16 genes, copy number 7: MRPL50P4, AC026391.1, SLC16A9, MRLN, CCDC6, LINC01553, ANK3, AL592430.1, Y_RNA, AL592430.2, ARL4AP1, ANK3-DT, CDK1, RHOBTB1, RNU2-72P, LINC00845.
- chr11:29,335,878–29,989,328, 1 gene, copy number 9 (within-gene range 2–9): LINC02755.
- chr11:29,594,326–32,104,665, 26 genes, copy number 7–10 (within-gene range 4–10): LINC02546, HNRNPRP2, AC107973.1, RN7SL240P, RPL7AP58, LINC01616, KCNA4, AL358944.1, AL358944.2, FSHB, ARL14EP, RPL12P30, MPPED2, AL353699.1, MPPED2-AS1, AL122014.1, DCDC1, CYCSP25, AL137804.1, DNAJC24, IMMP1L, ELP4, AC131571.1, PAX6, PAUPAR, AL035078.4.
- chr11:43,311,963–43,494,933, 8 genes, copy number 9: API5, AC087276.2, Y_RNA, TTC17, AC087276.3, AC087276.1, RN7SKP287, PPIAP41.
- chr11:68,612,899–70,398,488, 54 genes, copy number 11–18: AP003096.1, GAL, TESMIN, CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1.
- chr15:88,494,440–101,933,350, 340 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr17:46,029,916–46,225,389, 1 gene, copy number 5 (within-gene range 3–5): KANSL1.
- chr17:46,193,576–69,903,000, 688 genes, copy number 5–7 (within-gene range 1–7) (broad region; genes not listed).
- chr19:28,683,071–28,879,176, 3 genes, copy number 6: AC005524.1, MAN1A2P1, AC007795.1.
- chr19:28,892,931–28,895,949, 1 gene, copy number 6: AC008991.1.
- chr19:29,698,886–30,085,893, 14 genes, copy number 6: C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5.

Autosomal genes at a single copy (total copy number 1): 1,224. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
